Somatic mutation profile of tumor specimen TCGA-VR-A8EX-01A (aliquot TCGA-VR-A8EX-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.6 years (23,226 days).
Specimen TCGA-VR-A8EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da5ed167-dcf0-44a4-b4c1-067a4e94ab19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EX-10A (Blood Derived Normal), aliquot TCGA-VR-A8EX-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e74bb48-62d7-45ea-82c0-909ebbdb18aa

The open-access MAF lists 125 somatic variants for this specimen: 96 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 26, Nonsense Mutation 8, RNA 2, Frame Shift Ins 2, Splice Region 1, 5'Flank 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.3355A>G p.I1119V | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs1470241707; called by muse, mutect2, varscan2
- ADAM23 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 11/163 reads (7%) | catalogued as COSV100006931; called by muse, mutect2
- CASP14 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99693162; called by muse, mutect2, varscan2
- CCL5 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as rs1422786141; called by muse, mutect2, varscan2
- CD93 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1435635709, COSV55666851; called by muse, mutect2, varscan2
- CLSTN2 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776997183, COSV101515612, COSV71720340; called by muse, mutect2, varscan2
- CMYA5 | c.6566C>G p.S2189W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV71404296; called by muse, mutect2, varscan2
- CNTNAP2 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62167505; called by muse, mutect2, varscan2
- CSK | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99583634; called by muse, mutect2, varscan2
- CTNNBL1 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63746807; called by muse, mutect2
- DCDC1 | c.5096G>C p.R1699P (on ENST00000597505 / NM_001367979.1; = p.R806P on NM_020869.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375380625; called by muse, mutect2, varscan2
- DSEL | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778536579, COSV59489612; called by muse, mutect2, varscan2
- EIF6 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55773001; called by muse, mutect2, varscan2
- FAM71C | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60943062; called by muse, mutect2
- FBXL6 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs1554852816; called by muse, mutect2, varscan2
- FIGNL1 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63553184; called by mutect2, varscan2
- GGA1 | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.68); catalogued as rs756451398, COSV57329940; called by muse, mutect2, varscan2
- GLIS3 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1169929372; called by muse, mutect2, varscan2
- GUCA2B | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs747856024, COSV65367983; called by muse, mutect2, varscan2
- IL13 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs78181870; called by muse, mutect2, varscan2
- KBTBD7 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.039); catalogued as rs887220184; called by muse, mutect2, varscan2
- KIF26B | c.1792G>A p.V598M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770867836; called by muse, mutect2
- KIF27 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as rs748394033; called by muse, mutect2, varscan2
- LRRC7 | c.188C>A p.S63* (on ENST00000651989 / NM_001370785.2; = p.S30* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV50429413; called by muse, mutect2, varscan2
- MOCS3 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760591680, COSV99724210; called by muse, mutect2, varscan2
- NAALAD2 | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV58959598; called by muse, mutect2
- NADK | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58270747; called by mutect2, varscan2
- NIN | c.6156G>T p.R2052S (on ENST00000382041 / NM_182946.1; = p.R1339S on NM_016350.4) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs534805269, COSV55410859; called by muse, mutect2, varscan2
- NOC3L | c.1121C>G p.S374* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs1340077231, COSV64929578; called by muse, mutect2, varscan2
- NOS2 | c.2958C>G p.I986M | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58225672; called by muse, mutect2, varscan2
- NPHS1 | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.297); catalogued as rs769019215, CD024189; called by muse, mutect2, varscan2
- OR10K1 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222587425; called by muse, mutect2, varscan2
- OR2G3 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV60680663; called by muse, mutect2, varscan2
- OR2L8 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV61727419; called by muse, mutect2
- OR6N1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145448358, COSV100625192; called by muse, mutect2, varscan2
- PHF14 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as rs1437278236; called by muse, mutect2, varscan2
- REV1 | c.3270G>C p.L1090F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1171738520; called by muse, mutect2
- RGS18 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.552); catalogued as COSV100817675; called by muse, mutect2, varscan2
- SLC13A1 | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); catalogued as COSV52016796, COSV99520845; called by muse, mutect2, varscan2
- SLCO1B3 | c.1683G>T p.K561N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99680633; called by muse, mutect2
- STK31 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1562553573; called by muse, mutect2
- TATDN2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as rs760026472, COSV99813267; called by muse, mutect2, varscan2
- TBC1D32 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.175); catalogued as COSV51536068; called by muse, mutect2
- TLCD1 | c.452T>A p.L151H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772481817; called by muse, mutect2, varscan2
- TNFRSF25 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1185142187, COSV61067502; called by mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- UBN1 | c.1990G>C p.D664H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52174011; called by muse, mutect2
- UROC1 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52031186; called by muse, mutect2
- VCAM1 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54120006; called by muse, mutect2
- WDR33 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV59250150; called by muse, mutect2
- ZIK1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767832787, COSV56737729; called by muse, mutect2, varscan2
- ZNF791 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV58480615; called by muse, mutect2, varscan2
- ABL1 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAT1 | c.396_397insTC p.I133Sfs*3 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- ADAM20 | c.1716dup p.P573Sfs*16 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- AMDHD1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARHGEF26 | c.1894A>T p.M632L | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); called by muse, mutect2
- BHMT2 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CAPRIN1 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CASP8AP2 | c.2548C>G p.L850V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- FAM200A | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FANCI | c.3985T>C p.*1329Qext*6 (on ENST00000310775 / NM_001376911.1; = p.*1269Qext*6 on NM_018193.3) | Nonstop Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- FASLG | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- FGF5 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2
- FLG | c.6427G>A p.G2143R | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GRM3 | c.1456T>C p.W486R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HNF1A | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRNR | c.2857C>A p.H953N | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KANSL3 | c.1835A>T p.E612V (on ENST00000666923 / NM_001349262.2; = p.E586V on NM_001115016.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MAP1A | c.5831C>A p.T1944K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by mutect2, varscan2
- MICAL2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MISP | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MOV10 | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRM | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); called by mutect2, varscan2
- OR6C68 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDH7 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2
- PCDHGA2 | c.2424+8_2424+9del | Splice Region (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- PKHD1L1 | c.4707C>A p.S1569R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PODN | c.1076T>A p.L359Q (on ENST00000395871; = p.L311Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRPF8 | c.6594G>T p.K2198N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RALGPS2 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RERE | c.1009A>T p.M337L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SAP18 | c.384G>C p.Q128H (on ENST00000607003; = p.Q147H on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SCN1A | c.2311G>A p.D771N (on ENST00000303395 / NM_001202435.3; = p.D760N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- SLC16A9 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC18A2 | c.639T>A p.D213E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA6 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- SVEP1 | c.7411G>A p.E2471K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TRIM4 | c.1319A>T p.E440V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- UNC13D | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- WASHC2A | c.3802G>C p.D1268H | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK1 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- YEATS2 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZEB1 | c.870G>C p.K290N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF518B | c.2761A>T p.R921W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF750 | c.892del p.S298Lfs*68 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- BTBD6 | c.999C>T p.L333= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs371770383; called by muse, mutect2, varscan2
- C1orf52 | c.159G>A p.E53= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV99641017; called by muse, mutect2, varscan2
- CIZ1 | c.1158G>A p.Q386= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1026G>T p.R342= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- DOCK10 | c.459G>A p.E153= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- EGFLAM | c.261C>T p.S87= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs752980145; called by muse, mutect2, varscan2
- GAB3 | c.306G>A p.E102= | Silent (SNP) | VAF 18/25 reads (72%) | called by muse, mutect2, varscan2
- GALNT18 | c.816G>A p.R272= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs755784655; called by mutect2, varscan2
- H2AC17 | c.366G>A p.E122= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV100377582, COSV100377796; called by muse, mutect2, varscan2
- HDAC5 | c.2544A>T p.V848= | Silent (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- LRTM1 | c.339G>A p.L113= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1258186836, COSV55516819; called by muse, mutect2, varscan2
- MDN1 | c.5151A>T p.L1717= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- MMP24 | c.1726C>A p.R576= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.23178G>A p.A7726= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs762167753, COSV67495027; called by muse, mutect2, varscan2
- NAA50 | c.509G>A p.*170= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- NAALADL1 | c.141C>T p.T47= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs372762648; called by muse, mutect2
- NPAT | c.3306T>C p.N1102= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1201841114; called by muse, mutect2, varscan2
- PADI3 | c.840G>T p.S280= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- PAQR5 | c.312C>T p.F104= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1320G>C p.R440= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1354657120; called by mutect2, varscan2
- SRD5A2 | c.198G>T p.G66= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs760689799; called by mutect2, varscan2
- TRABD2A | c.1173C>T p.A391= (on ENST00000409520 / NM_001277053.2; = p.A342= on NM_001080824.3) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs748011854, COSV52849965; called by muse, mutect2, varscan2
- TRRAP | c.7413C>T p.Y2471= (on ENST00000359863 / NM_001244580.1; = p.Y2453= on NM_003496.3) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs771243011; called by muse, mutect2, varscan2
- UBN1 | c.1632T>A p.A544= | Silent (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- VPS4A | c.381C>T p.N127= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs759037249; called by muse, mutect2, varscan2
- ZNF799 | c.1800C>G p.L600= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- DCHS2 | n.5244G>C | RNA (SNP) | VAF 5/61 reads (8%) | catalogued as COSV61772460; called by muse, mutect2
- MIR515-2 | n.70G>A | RNA (SNP) | VAF 15/81 reads (19%) | catalogued as rs372763623; called by muse, mutect2, varscan2
- PPM1A | chr14:60246021 G>A | 5'Flank (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
